Somatic mutation profile of tumor specimen MMRF_2039_1_BM_CD138pos (aliquot MMRF_2039_1_BM_CD138pos_T1_KHS5U_L08818) from MMRF case MMRF_2039, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.4 years (25,715 days).
Specimen MMRF_2039_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd460795-a13d-4eb9-b63e-7a8aebcad9aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2039_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2039_1_PB_CD3pos_C3_KHS5U_L08839; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5652d384-79f2-44f4-8f43-0eb8cbb2213d

The open-access MAF lists 135 somatic variants for this specimen: 44 protein-altering or splice-affecting, 7 silent, 84 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 50, Missense Mutation 36, Intron 24, Silent 7, 5'UTR 5, 3'Flank 2, Splice Region 2, RNA 2, In Frame Del 2, 5'Flank 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DARS1 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587776985, CM133676; ClinVar: pathogenic; called by mutect2, varscan2
- ARHGAP26 | c.1301C>G p.S434C | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV50828845; called by muse, mutect2, varscan2
- COL17A1 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1204758676; called by muse, mutect2, varscan2
- CTTNBP2 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV50413012; called by muse, varscan2
- ECT2 | c.961C>G p.L321V (on ENST00000392692 / NM_001349098.2; = p.L290V on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs1420843429, COSV99221444; called by mutect2, varscan2
- GIPC3 | c.925C>T p.R309W (on ENST00000644946; = p.I304= on NM_133261.3) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as rs748777903, COSV59260277; called by muse, mutect2, varscan2
- GPR158 | c.3322C>T p.R1108C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs372238950, COSV66267514; called by muse, mutect2, varscan2
- HIVEP3 | c.5252G>A p.R1751Q | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746325865, COSV56008983; called by muse, mutect2, varscan2
- IGLL5 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs762998471, COSV73248971, COSV73251039; called by muse, mutect2, varscan2
- KIF1A | c.2801C>T p.S934L | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as rs764873243, COSV57485399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTMR11 | c.1124-7C>T | Splice Region (SNP) | VAF 13/33 reads (39%) | catalogued as rs1553767657; called by muse, mutect2, varscan2
- NEK9 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV53131347; called by muse, mutect2, varscan2
- P3H2 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.449); catalogued as rs549590724; called by muse, mutect2, varscan2
- PPFIA2 | c.2921G>C p.R974P | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61045372; called by muse, mutect2, varscan2
- PTPRU | c.3107G>T p.G1036V | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100113447; called by muse, mutect2, varscan2
- RB1 | c.1901C>A p.S634* | Nonsense Mutation (SNP) | VAF 6/100 reads (6%) | catalogued as CM961233, COSV57296525, COSV57302654; called by muse, mutect2
- SLCO1B3 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV53942827; called by muse, mutect2, varscan2
- SPRTN | c.305G>C p.R102T | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV50480396; called by muse, mutect2, varscan2
- STBD1 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.154); catalogued as COSV99421561; called by muse, mutect2, varscan2
- SYNJ1 | c.2905_2910del p.L969_I970del | In Frame Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs747135111; called by pindel, varscan2
- ZNF512B | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as rs778825361; called by muse, mutect2, varscan2
- AC131160.1 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.044); called by muse, mutect2
- BEGAIN | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CACNA1I | c.3787_3795del p.G1263_A1265del | In Frame Del (DEL) | VAF 22/106 reads (21%) | called by mutect2, varscan2
- CDK5RAP3 | c.1493C>G p.P498R | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, varscan2
- DLGAP4 | c.827C>A p.T276N | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DMTF1 | c.1650+1G>A p.X550_splice | Splice Site (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
- ERICH6B | c.1902G>T p.M634I | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2
- GLDC | c.1762G>T p.A588S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); called by mutect2, varscan2
- HAUS8 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- HIVEP1 | c.2870C>T p.T957I | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAN2B1 | c.2665-6C>T | Splice Region (SNP) | VAF 9/37 reads (24%) | called by mutect2, varscan2
- MYH4 | c.1879del p.A627Hfs*33 | Frame Shift Del (DEL) | VAF 30/80 reads (38%) | called by mutect2, varscan2
- MYO1F | c.2965C>A p.L989M | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by mutect2, varscan2
- NISCH | c.3779G>T p.R1260L | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PCDHGA10 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHYKPL | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- POLD1 | c.2229dup p.G744Wfs*12 | Frame Shift Ins (INS) | VAF 57/225 reads (25%) | called by mutect2, pindel, varscan2
- RANBP1 | c.386C>G p.A129G | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- RRM2B | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.217); called by muse, varscan2
- SHOC1 | c.2944G>T p.A982S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAM | c.731A>C p.D244A | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBE3A | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- ZNF347 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by mutect2, varscan2
- AOPEP | c.2154C>G p.L718= (on ENST00000375315 / NM_001193329.1; = p.L619= on NM_032823.5) | Silent (SNP) | VAF 33/136 reads (24%) | called by muse, mutect2, varscan2
- CMYA5 | c.11028G>A p.E3676= | Silent (SNP) | VAF 42/139 reads (30%) | called by muse, mutect2, varscan2
- DOCK4 | c.4638G>A p.L1546= | Silent (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- RSPH14 | c.699C>A p.I233= | Silent (SNP) | VAF 43/118 reads (36%) | called by muse, mutect2, varscan2
- SNAPC4 | c.174C>T p.I58= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as rs749143015; called by muse, mutect2, varscan2
- TNFSF14 | c.345G>A p.E115= | Silent (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- ZNF219 | c.1134C>G p.L378= | Silent (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- AASDHPPT | c.*1445G>A | 3'UTR (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- AC112484.1 | n.820C>T | RNA (SNP) | VAF 24/111 reads (22%) | catalogued as rs1274125360; called by muse, mutect2, varscan2
- ADAMTS4 | c.*833T>A | 3'UTR (SNP) | VAF 12/55 reads (22%) | called by mutect2, varscan2
- AGO4 | c.*776del | 3'UTR (DEL) | VAF 25/56 reads (45%) | catalogued as rs149653098; called by mutect2, varscan2
- ASPM | c.-227C>T | 5'UTR (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- ATP6V1C1 | c.*3404C>G | 3'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, varscan2
- AZIN1 | c.*1931G>T | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- C20orf96 | c.*261C>T | 3'UTR (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- C2CD5 | c.-12G>A | 5'UTR (SNP) | VAF 75/175 reads (43%) | catalogued as rs779130024; called by muse, mutect2, varscan2
- CCDC85C | c.*8258C>G | 3'UTR (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2
- CCN1 | c.278-50G>A | Intron (SNP) | VAF 20/53 reads (38%) | called by mutect2, varscan2
- CD200R1 | c.*305G>T | 3'UTR (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- CDCA7 | c.*754del | 3'UTR (DEL) | VAF 28/71 reads (39%) | called by mutect2, pindel, varscan2
- CFAP44 | c.*832T>C | 3'UTR (SNP) | VAF 28/109 reads (26%) | called by muse, mutect2, varscan2
- CHRM3 | c.*5143T>C | 3'UTR (SNP) | VAF 41/102 reads (40%) | called by muse, mutect2, varscan2
- CLDND1 | c.*525A>C | 3'UTR (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- COL5A1 | c.*1866G>A | 3'UTR (SNP) | VAF 66/184 reads (36%) | called by muse, varscan2
- CXCR2 | c.*713G>C | 3'UTR (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- DCP2 | c.*2786G>A | 3'UTR (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
- DDX51 | c.1251-34G>C | Intron (SNP) | VAF 15/22 reads (68%) | called by muse, mutect2, varscan2
- DENND3 | c.3396+54G>A | Intron (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- DOK1 | c.-623C>T | 5'UTR (SNP) | VAF 47/158 reads (30%) | called by muse, mutect2, varscan2
- DUSP5 | c.*842C>T | 3'UTR (SNP) | VAF 38/95 reads (40%) | called by muse, mutect2, varscan2
- DYSF | c.88+12801G>A | Intron (SNP) | VAF 18/105 reads (17%) | catalogued as rs972675695; ClinVar: likely benign; called by muse, mutect2, varscan2
- EGFLAM | c.*233G>A | 3'UTR (SNP) | VAF 33/124 reads (27%) | called by muse, mutect2, varscan2
- EIF3FP3 | n.127C>T | RNA (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- FADS1 | c.376-201C>T | Intron (SNP) | VAF 39/80 reads (49%) | catalogued as rs1053873018; called by muse, mutect2, varscan2
- FBXO7 | c.-19C>T | 5'UTR (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- FOXD1 | c.*13A>G | 3'UTR (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- FUZ | c.690+25G>A | Intron (SNP) | VAF 42/134 reads (31%) | called by muse, mutect2, varscan2
- GAPT | c.*750C>T | 3'UTR (SNP) | VAF 30/123 reads (24%) | called by mutect2, varscan2
- GUCD1 | c.*1289G>A | 3'UTR (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- GXYLT2 | c.*1736A>T | 3'UTR (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2
- HHIP | c.*2466G>T | 3'UTR (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
- IL1RAP | c.*974G>A | 3'UTR (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- INSL5 | c.*250T>A | 3'UTR (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- IRAK3 | c.*3647G>A | 3'UTR (SNP) | VAF 14/47 reads (30%) | called by muse, varscan2
- KCND3 | chr1:111772916 C>T | 3'Flank (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- KIFC3 | c.316-2559C>T | Intron (SNP) | VAF 25/35 reads (71%) | called by muse, mutect2, varscan2
- LIN54 | c.*2545C>G | 3'UTR (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- LRATD2 | c.*1152C>T | 3'UTR (SNP) | VAF 16/27 reads (59%) | called by muse, mutect2, varscan2
- MAP6 | c.-368T>A | 5'UTR (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- MCOLN3 | c.*470A>G | 3'UTR (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- MRPS27 | c.*711G>C | 3'UTR (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- MST1L | n.1515-125G>A | Intron (SNP) | VAF 14/45 reads (31%) | called by muse, varscan2
- MYO15A | c.8788+48C>T | Intron (SNP) | VAF 34/94 reads (36%) | catalogued as rs1015170607; called by muse, mutect2, varscan2
- NAA60 | c.572+22G>A | Intron (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2
- NCDN | c.*82G>C | 3'UTR (SNP) | VAF 12/36 reads (33%) | catalogued as rs1557427581; called by muse, mutect2
- NEUROD4 | c.*1462C>T | 3'UTR (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- NHLH2 | chr1:115843909 G>A | 5'Flank (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- OLFML2A | c.670-480C>T | Intron (SNP) | VAF 58/229 reads (25%) | called by muse, mutect2, varscan2
- PAWR | c.*1780A>G | 3'UTR (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- PCYT1B | c.*1201C>G | 3'UTR (SNP) | VAF 17/19 reads (89%) | called by muse, mutect2, varscan2
- PFKFB4 | c.988-26G>A | Intron (SNP) | VAF 32/94 reads (34%) | catalogued as rs745489743; called by muse, varscan2
- PKP2 | c.*775A>G | 3'UTR (SNP) | VAF 34/75 reads (45%) | catalogued as rs543832696; called by muse, mutect2, varscan2
- PLIN4 | c.*1991C>T | 3'UTR (SNP) | VAF 28/166 reads (17%) | catalogued as rs541102612; called by muse, mutect2, varscan2
- PLPP5 | c.463+180C>G | Intron (SNP) | VAF 29/58 reads (50%) | called by muse, varscan2
- PNPLA8 | c.*1437C>A | 3'UTR (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- PPP2R2C | c.71-527A>T | Intron (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- PSMA3 | c.590+154G>T | Intron (SNP) | VAF 12/14 reads (86%) | called by mutect2, varscan2
- RALB | c.*676C>T | 3'UTR (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- RAN | chr12:130876608 A>G | 3'Flank (SNP) | VAF 27/52 reads (52%) | catalogued as rs938153598; called by muse, mutect2, varscan2
- RGS4 | c.*854G>A | 3'UTR (SNP) | VAF 36/132 reads (27%) | catalogued as rs1177725564; called by muse, varscan2
- RGS7BP | c.333-9C>T | Intron (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- RO60 | c.-22+274C>T | Intron (SNP) | VAF 54/183 reads (30%) | catalogued as rs960085318; called by muse, varscan2
- RPS6KC1 | c.2821+113C>T | Intron (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- RUNX1 | c.*1761G>A | 3'UTR (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- SLC44A1 | c.*2472A>G | 3'UTR (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- SLC9A2 | c.*1933C>T | 3'UTR (SNP) | VAF 23/144 reads (16%) | called by muse, mutect2, varscan2
- SPAG9 | c.*635C>T | 3'UTR (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- TAZ | c.284+44C>T | Intron (SNP) | VAF 17/65 reads (26%) | catalogued as rs1488804193; called by muse, mutect2, varscan2
- TMEM38B | c.*2164C>T | 3'UTR (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- TMPRSS4 | c.*1082G>C | 3'UTR (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.1196+264C>G | Intron (SNP) | VAF 9/17 reads (53%) | called by muse, varscan2
- TMPRSS6 | c.1196+202C>T | Intron (SNP) | VAF 12/20 reads (60%) | called by muse, varscan2
- TNFRSF14 | c.304+632A>G | Intron (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- TSC22D3 | c.*987G>C | 3'UTR (SNP) | VAF 43/44 reads (98%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.*385G>A | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- USH2A | c.7451+15T>G | Intron (SNP) | VAF 29/46 reads (63%) | called by muse, mutect2, varscan2
- USP53 | c.*273G>A | 3'UTR (SNP) | VAF 38/80 reads (48%) | called by muse, mutect2, varscan2
- XPR1 | c.1808+93G>C | Intron (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2
- ZFAND5 | c.*3619C>T | 3'UTR (SNP) | VAF 20/69 reads (29%) | catalogued as rs1015773440; called by mutect2, varscan2
- ZNF396 | c.*1010A>T | 3'UTR (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- ZNF594 | c.*1621G>A | 3'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
